Somatic mutation profile of tumor specimen TCGA-29-1698-01A (aliquot TCGA-29-1698-01A-01W-0633-09) from TCGA case TCGA-29-1698, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 53.7 years (19,611 days).
Specimen TCGA-29-1698-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f6e16c8e-c7c9-4070-a536-db943f7aef3b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-29-1698-10A (Blood Derived Normal), aliquot TCGA-29-1698-10A-01W-0633-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ef9aef97-131c-4832-8ed5-4ac540be703b

The open-access MAF lists 87 somatic variants for this specimen: 68 protein-altering or splice-affecting, 17 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 17, Nonsense Mutation 4, Frame Shift Del 2, In Frame Del 2, Intron 1, Splice Region 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MCOLN1 | c.615dup p.S206Qfs*36 | Frame Shift Ins (INS) | VAF 5/34 reads (15%) | catalogued as rs886041533; ClinVar: pathogenic; called by pindel, varscan2
- TP53 | c.577C>T p.H193Y | Missense Mutation (SNP) | VAF 151/214 reads (71%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876658468, COSV52675896, COSV52688299, COSV52757395; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.12122G>C p.S4041T | Missense Mutation (SNP) | VAF 51/770 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV101446715; called by muse, mutect2
- C11orf49 | c.17G>T p.R6L | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV53566137; called by muse, mutect2, varscan2
- CASR | c.950C>A p.T317N | Missense Mutation (SNP) | VAF 25/401 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as COSV99948367; called by muse, mutect2
- CCDC136 | c.2015G>T p.C672F | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.147); catalogued as COSV99921990; called by muse, mutect2
- CFAP65 | c.471G>T p.E157D (on ENST00000341552 / NM_194302.4; = p.E92D on NM_152389.4) | Missense Mutation (SNP) | VAF 61/501 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as COSV55390378; called by muse, mutect2, varscan2
- CLMN | c.2093A>T p.E698V | Missense Mutation (SNP) | VAF 39/230 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54182355; called by muse, mutect2, varscan2
- COMMD9 | c.457A>C p.I153L | Missense Mutation (SNP) | VAF 24/163 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.981); catalogued as COSV54672484; called by muse, mutect2, varscan2
- CP | c.779A>G p.Y260C | Missense Mutation (SNP) | VAF 292/796 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV52830754; called by muse, mutect2, varscan2
- CYB5R4 | c.976T>C p.Y326H | Missense Mutation (SNP) | VAF 19/154 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63750884; called by muse, mutect2, varscan2
- DCAF4L2 | c.734C>G p.S245C | Missense Mutation (SNP) | VAF 20/318 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.167); catalogued as COSV100150407, COSV99081983; called by muse, mutect2
- DCX | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 166/641 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.323); catalogued as COSV57569676; called by muse, mutect2, varscan2
- ERCC6 | c.1742G>A p.W581* | Nonsense Mutation (SNP) | VAF 65/206 reads (32%) | catalogued as COSV63390228; called by muse, mutect2, varscan2
- FGD6 | c.3751G>C p.V1251L | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV59693384, COSV59695529; called by muse, mutect2, varscan2
- FLNB | c.218G>T p.R73L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.284); catalogued as COSV55879971; called by muse, mutect2, varscan2
- FOXK2 | c.1084C>A p.L362M | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.615); catalogued as COSV100081724, COSV58878322; called by muse, mutect2
- FOXP2 | c.631G>C p.A211P | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.329); catalogued as COSV100646141; called by muse, mutect2
- GAS2 | c.670G>T p.E224* | Nonsense Mutation (SNP) | VAF 9/119 reads (8%) | catalogued as COSV99534555; called by muse, mutect2
- GP2 | c.1309C>A p.Q437K (on ENST00000381362 / NM_001007240.3; = p.Q434K on NM_001502.4) | Missense Mutation (SNP) | VAF 15/203 reads (7%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV100221197; called by muse, mutect2
- GREB1 | c.4047C>T p.I1349= | Splice Region (SNP) | VAF 46/116 reads (40%) | catalogued as rs781383668, COSV52184405; called by muse, mutect2, varscan2
- HECW1 | c.3992C>A p.S1331Y | Missense Mutation (SNP) | VAF 33/681 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV101222596; called by muse, mutect2
- IGKJ5 | c.36T>G p.I12M | Missense Mutation (SNP) | VAF 25/228 reads (11%) | catalogued as rs372745823; called by muse, mutect2
- IL1RAPL1 | c.1049A>C p.H350P | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.359); catalogued as COSV56262803; called by muse, mutect2, varscan2
- ISCU | c.329A>C p.K110T (on ENST00000311893 / NM_213595.4; = p.K85T on NM_014301.4) | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV57207499; called by muse, mutect2, varscan2
- KATNIP | c.4655C>A p.T1552N | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55180994; called by muse, mutect2, varscan2
- MIER2 | c.127C>T p.Q43* | Nonsense Mutation (SNP) | VAF 8/41 reads (20%) | catalogued as rs764795025, COSV53395855; called by muse, mutect2, varscan2
- MSH5 | c.1769T>A p.I590N | Missense Mutation (SNP) | VAF 71/279 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV65209742; called by muse, mutect2, varscan2
- NIPBL | c.7501C>T p.R2501W | Missense Mutation (SNP) | VAF 15/243 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as rs1324046982, COSV56966921; called by muse, mutect2
- NOP2 | c.1976C>A p.S659* (on ENST00000322166 / NM_001258308.2; = p.S655* on NM_006170.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 96/205 reads (47%) | catalogued as COSV59110688; called by muse, mutect2, varscan2
- NUMA1 | c.4291G>A p.A1431T | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as rs370967498; called by muse, mutect2, varscan2
- OR1L4 | c.206T>C p.F69S | Missense Mutation (SNP) | VAF 56/365 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.253); catalogued as COSV52340483; called by muse, mutect2, varscan2
- PIK3R4 | c.3887A>C p.E1296A | Missense Mutation (SNP) | VAF 7/146 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); catalogued as COSV100649685; called by muse, mutect2
- PKHD1L1 | c.1273G>C p.E425Q | Missense Mutation (SNP) | VAF 22/278 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.057); catalogued as COSV101005150; called by muse, mutect2
- PLB1 | c.3487A>G p.T1163A | Missense Mutation (SNP) | VAF 59/804 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.519); catalogued as COSV100577394; called by muse, mutect2
- PPP1R16B | c.1115G>T p.S372I | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.042); catalogued as COSV100238853; called by muse, mutect2
- PRSS58 | c.677A>T p.K226I | Missense Mutation (SNP) | VAF 41/235 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV73488660; called by muse, mutect2, varscan2
- PSEN2 | c.763A>T p.I255F | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs201292728, COSV60916384; called by muse, mutect2, varscan2
- PTGS1 | c.1745C>T p.P582L | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs201836968, COSV56291933; called by muse, mutect2, varscan2
- PTK2 | c.16C>G p.L6V | Missense Mutation (SNP) | VAF 34/411 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100569246; called by muse, mutect2
- RAB36 | c.440T>G p.V147G | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.491); catalogued as COSV54075047; called by muse, mutect2, varscan2
- RAPGEFL1 | c.934G>T p.G312C | Missense Mutation (SNP) | VAF 40/55 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52863248; called by muse, mutect2, varscan2
- RGS7 | c.869A>C p.Y290S | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV58542580; called by muse, mutect2, varscan2
- RPL22L1 | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as rs751661574, COSV55556891; called by muse, mutect2, varscan2
- SAP130 | c.3135G>C p.K1045N | Missense Mutation (SNP) | VAF 81/387 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.73); catalogued as COSV52097370; called by muse, mutect2, varscan2
- SCAF4 | c.2527C>A p.Q843K | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.643); catalogued as COSV54255604, COSV54256500; called by muse, mutect2
- SLMAP | c.843T>A p.N281K | Missense Mutation (SNP) | VAF 34/233 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55847797; called by muse, mutect2, varscan2
- SMOC1 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 36/172 reads (21%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.91); catalogued as rs745832952, COSV62759291; called by muse, mutect2, varscan2
- SPOUT1 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1447139682, COSV63509281; called by muse, mutect2, varscan2
- SPTBN2 | c.6355T>A p.S2119T | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0.009); catalogued as COSV59452381; called by muse, mutect2, varscan2
- SUGP2 | c.1304G>A p.R435Q | Missense Mutation (SNP) | VAF 20/218 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as COSV100431307; called by muse, mutect2
- SYNJ2 | c.3397C>T p.H1133Y | Missense Mutation (SNP) | VAF 17/203 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.656); catalogued as COSV100839988; called by muse, mutect2
- TBRG4 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs765139663, COSV51832736; called by muse, mutect2, varscan2
- TMEM130 | c.437C>A p.P146H | Missense Mutation (SNP) | VAF 17/216 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV100228506; called by muse, mutect2
- TNIK | c.4019G>C p.R1340P | Missense Mutation (SNP) | VAF 21/285 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52675435, COSV99454445; called by muse, mutect2
- TSGA13 | c.259G>C p.V87L | Missense Mutation (SNP) | VAF 17/171 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100746761; called by muse, mutect2
- USH2A | c.15346C>T p.R5116C | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs759899869, COSV56372322; called by muse, mutect2, varscan2
- USP6NL | c.1399G>T p.A467S | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs1011814771, COSV53211585; called by muse, mutect2, varscan2
- WSB2 | c.837C>G p.H279Q | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV99969730; called by muse, mutect2
- ZNF311 | c.1626G>C p.L542F | Missense Mutation (SNP) | VAF 25/245 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.409); catalogued as rs778141417, COSV101014054; called by muse, mutect2, varscan2
- ZNF708 | c.211G>T p.A71S | Missense Mutation (SNP) | VAF 24/446 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as COSV100803026; called by muse, mutect2
- ZNF79 | c.611A>G p.Y204C | Missense Mutation (SNP) | VAF 85/689 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.788); catalogued as rs761070280, COSV61070968; called by muse, mutect2, varscan2
- ZNF804B | c.2465C>G p.S822C | Missense Mutation (SNP) | VAF 26/281 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV100301350, COSV100306036; called by muse, mutect2
- C2CD3 | c.3942_3946delinsGA p.E1315_Y1316delinsN | In Frame Del (DEL) | VAF 27/179 reads (15%) | called by pindel, varscan2*
- COPB1 | c.1237_1239del p.N413del | In Frame Del (DEL) | VAF 33/96 reads (34%) | called by pindel, varscan2
- NELFE | c.18del p.G7Dfs*2 | Frame Shift Del (DEL) | VAF 24/115 reads (21%) | called by mutect2, pindel, varscan2
- PRAMEF19 | c.315G>T p.M105I | Missense Mutation (SNP) | VAF 152/774 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, varscan2
- RNASEH2B | c.582_588del p.F194Lfs*20 | Frame Shift Del (DEL) | VAF 31/244 reads (13%) | called by mutect2, pindel, varscan2
- ABCA13 | c.4278T>C p.D1426= | Silent (SNP) | VAF 8/192 reads (4%) | catalogued as COSV101329894; called by muse, mutect2
- ACRBP | c.1389G>A p.E463= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as COSV57523941; called by muse, mutect2, varscan2
- ASB15 | c.285T>A p.V95= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as COSV99306089; called by muse, mutect2
- BAZ1A | c.4320A>G p.Q1440= | Silent (SNP) | VAF 26/122 reads (21%) | catalogued as rs773421635, COSV62410293; called by muse, mutect2, varscan2
- BLVRA | c.393G>A p.E131= | Silent (SNP) | VAF 15/308 reads (5%) | catalogued as COSV99645861; called by muse, mutect2
- GGA3 | c.306G>T p.L102= (on ENST00000537686 / NM_138619.4; = p.L69= on NM_014001.5) | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as COSV55456849; called by muse, mutect2, varscan2
- GK5 | c.432A>G p.R144= | Silent (SNP) | VAF 79/224 reads (35%) | catalogued as COSV67485790; called by muse, mutect2, varscan2
- GPR141 | c.222C>G p.T74= | Silent (SNP) | VAF 42/794 reads (5%) | catalogued as COSV100550200; called by muse, mutect2
- HSPB9 | c.459G>A p.K153= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as COSV56790975; called by muse, mutect2, varscan2
- LSAMP | c.300G>A p.K100= | Silent (SNP) | VAF 13/144 reads (9%) | catalogued as rs1457567331, COSV100368730; called by muse, mutect2
- PAK6 | c.1884C>T p.S628= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs762033045, COSV53045728; called by muse, mutect2, varscan2
- PRKCA | c.1659C>T p.H553= | Silent (SNP) | VAF 5/114 reads (4%) | called by muse, mutect2
- SIGLEC7 | c.813T>C p.S271= | Silent (SNP) | VAF 40/369 reads (11%) | catalogued as rs776981304, COSV58315885; called by muse, mutect2, varscan2
- SLC37A3 | c.1119G>A p.G373= | Silent (SNP) | VAF 10/256 reads (4%) | catalogued as COSV100405232; called by muse, mutect2
- SP110 | c.1884G>C p.T628= | Silent (SNP) | VAF 21/209 reads (10%) | catalogued as COSV99282905; called by muse, mutect2
- TFDP1 | c.606T>C p.C202= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as COSV64740525; called by muse, mutect2, varscan2
- VPS53 | c.411C>T p.H137= (on ENST00000571805 / NM_001366253.2; = p.H108= on NM_018289.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/112 reads (18%) | catalogued as rs765870836, COSV52130943; called by muse, varscan2
- MACF1 | c.15832-11673G>A | Intron (SNP) | VAF 195/357 reads (55%) | catalogued as COSV57121727; called by muse, mutect2, varscan2
- XIST | n.9547C>A | RNA (SNP) | VAF 14/51 reads (27%) | called by muse, mutect2, varscan2
